CCDI case PBCHFI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aaca945a-9493-4bff-8dde-619a3c05dc3e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 13.1 years (4,783 days).

Biospecimens (3 samples)
- Sample 0DS28Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS291: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS29T: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
